Somatic mutation profile of tumor specimen C3L-01465-01 (aliquot CPT0085790009) from CPTAC case C3L-01465, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 67.4 years (24,603 days).
Specimen C3L-01465-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abbf1039-eab7-462b-81aa-8d2781fa2525.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01465-31 (Blood Derived Normal), aliquot CPT0086650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb85c73d-62dc-4812-945e-5365b53e80a0

The open-access MAF lists 71 somatic variants for this specimen: 44 protein-altering or splice-affecting, 18 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 18, Frame Shift Del 6, Intron 6, Nonsense Mutation 4, RNA 2, Frame Shift Ins 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs1182844289, CM157251; called by muse, mutect2, varscan2
- ATP5F1B | c.1234A>G p.I412V | Missense Mutation (SNP) | VAF 247/566 reads (44%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1051700160; called by muse, mutect2, varscan2
- CMKLR1 | c.457G>A p.V153I (on ENST00000312143 / NM_001142344.2; = p.V151I on NM_004072.3) | Missense Mutation (SNP) | VAF 47/371 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.045); catalogued as rs774689822, COSV56438976; called by muse, mutect2, varscan2
- FAM155B | c.1213C>A p.H405N | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV52935433; called by muse, mutect2
- FAM205A | c.3797C>T p.T1266M | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as rs757248372, COSV66489711, COSV66490432; called by muse, mutect2, varscan2
- FMNL1 | c.2675C>T p.P892L | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs780542974; called by muse, mutect2, varscan2
- GLUD2 | c.1267T>G p.L423V | Missense Mutation (SNP) | VAF 174/283 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as COSV60151257; called by muse, mutect2, varscan2
- IGSF10 | c.3052G>A p.G1018R | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs372539492; called by muse, mutect2, varscan2
- JHY | c.527del p.G176Efs*21 | Frame Shift Del (DEL) | VAF 165/389 reads (42%) | catalogued as COSV56219252; called by mutect2, pindel, varscan2
- PKHD1 | c.11252A>G p.D3751G | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as rs979295600; called by muse, mutect2, varscan2
- PLCXD1 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 103/797 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs141404099, COSV58205961; called by muse, mutect2, varscan2
- SLITRK6 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1201478731, COSV68391234; called by muse, mutect2
- TTN | c.37234G>A p.E12412K (on ENST00000591111; = p.E4988K on NM_003319.4) | Missense Mutation (SNP) | VAF 69/355 reads (19%) | PolyPhen possibly damaging (0.885); catalogued as rs759050071, COSV59934362, COSV60261806; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VHL | c.555C>A p.Y185* | Nonsense Mutation (SNP) | VAF 194/510 reads (38%) | catalogued as CM130354, CM941390, COSV56542593, COSV56543143, COSV56546536, COSV56553859; called by muse, mutect2, varscan2
- ZBED1 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 119/350 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs749425836; called by muse, mutect2, varscan2
- AGRP | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- BUD31 | c.164A>G p.Q55R | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- C7orf26 | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- CFHR5 | c.1492T>A p.S498T | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- COL5A2 | c.296del p.T99Nfs*22 | Frame Shift Del (DEL) | VAF 50/376 reads (13%) | called by mutect2, pindel, varscan2
- COPS2 | c.793T>C p.Y265H | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DSP | c.1377dup p.P460Tfs*9 | Frame Shift Ins (INS) | VAF 48/180 reads (27%) | called by mutect2, pindel, varscan2
- FANCM | c.1963A>C p.N655H | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- FNIP2 | c.1221_1224del p.L408Kfs*16 | Frame Shift Del (DEL) | VAF 23/191 reads (12%) | called by mutect2, pindel, varscan2
- FRYL | c.4460T>C p.M1487T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.303); called by muse, mutect2
- HES3 | c.558C>A p.N186K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HIP1R | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 105/259 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- INAVA | c.1331del p.P444Rfs*128 | Frame Shift Del (DEL) | VAF 112/322 reads (35%) | called by mutect2, pindel, varscan2
- LAMP1 | c.739A>T p.K247* | Nonsense Mutation (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2
- LETM2 | c.726G>T p.R242S (on ENST00000379957 / NM_001286819.2; = p.R147S on NM_144652.3) | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ME2 | c.151C>G p.Q51E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MYH11 | c.2652+4C>A | Splice Region (SNP) | VAF 149/783 reads (19%) | called by muse, mutect2, varscan2
- NAPA | c.723C>A p.C241* | Nonsense Mutation (SNP) | VAF 26/160 reads (16%) | called by muse, mutect2, varscan2
- NUDT13 | c.269T>C p.I90T | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- OR5R1 | c.244A>G p.M82V | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDP1 | c.600del p.F200Lfs*13 | Frame Shift Del (DEL) | VAF 413/889 reads (46%) | called by mutect2, pindel, varscan2
- PPFIA3 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SDR39U1 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 77/473 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- SLITRK5 | c.635T>G p.L212R | Missense Mutation (SNP) | VAF 41/295 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SUN2 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- TEPP | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TTN | c.12979G>T p.V4327L (on ENST00000591111; = p.V4281L on NM_003319.4) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | called by muse, varscan2
- UTRN | c.1003del p.Q335Rfs*22 | Frame Shift Del (DEL) | VAF 36/156 reads (23%) | called by mutect2, pindel, varscan2
- ZNF490 | c.1525A>G p.K509E | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, varscan2
- ASCC1 | c.873A>G p.A291= (on ENST00000342444 / NM_001369085.1; = p.A263= on NM_001198798.2 and 8 other RefSeq transcripts) | Silent (SNP) | VAF 133/324 reads (41%) | catalogued as rs1279793312; called by muse, mutect2, varscan2
- ATF6 | c.1758C>T p.T586= | Silent (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- DSG4 | c.177A>G p.R59= | Silent (SNP) | VAF 114/552 reads (21%) | called by muse, varscan2
- FBN2 | c.708G>A p.K236= | Silent (SNP) | VAF 56/632 reads (9%) | called by muse, mutect2
- GOLGA5 | c.258A>G p.V86= | Silent (SNP) | VAF 44/262 reads (17%) | called by muse, mutect2, varscan2
- ITPR3 | c.7821C>T p.A2607= | Silent (SNP) | VAF 84/497 reads (17%) | catalogued as rs1305327262; called by muse, mutect2, varscan2
- KLHL1 | c.849G>A p.E283= | Silent (SNP) | VAF 52/129 reads (40%) | catalogued as COSV100917342; called by muse, mutect2, varscan2
- PGLYRP3 | c.243C>T p.C81= | Silent (SNP) | VAF 37/175 reads (21%) | catalogued as rs372903915, COSV99319451; called by muse, mutect2, varscan2
- RANBP3 | c.909C>T p.I303= (on ENST00000340578 / NM_007322.3; = p.I298= on NM_003624.3) | Silent (SNP) | VAF 41/204 reads (20%) | called by muse, mutect2, varscan2
- RYR1 | c.11676G>A p.E3892= | Silent (SNP) | VAF 54/331 reads (16%) | called by muse, mutect2, varscan2
- SEMA4D | c.855C>T p.D285= | Silent (SNP) | VAF 47/232 reads (20%) | called by muse, mutect2, varscan2
- SPEN | c.321C>T p.F107= | Silent (SNP) | VAF 48/193 reads (25%) | catalogued as rs1173538746; called by muse, mutect2, varscan2
- SYT12 | c.1050C>T p.F350= | Silent (SNP) | VAF 78/264 reads (30%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.891A>T p.S297= | Silent (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- URAD | c.378C>T p.S126= | Silent (SNP) | VAF 36/155 reads (23%) | called by muse, mutect2, varscan2
- WDR18 | c.1239C>A p.R413= | Silent (SNP) | VAF 43/278 reads (15%) | called by muse, mutect2, varscan2
- ZFAT | c.1974G>A p.Q658= | Silent (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2
- ZYG11A | c.1956A>T p.I652= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- KLF6 | c.*406_*407del | 3'UTR (DEL) | VAF 58/199 reads (29%) | called by mutect2, pindel, varscan2
- LINC01537 | n.114C>T | RNA (SNP) | VAF 36/87 reads (41%) | catalogued as rs955178335; called by muse, mutect2, varscan2
- LINC01567 | n.431_434del | RNA (DEL) | VAF 42/123 reads (34%) | called by mutect2, pindel, varscan2
- NACA | c.70+3714C>T | Intron (SNP) | VAF 69/247 reads (28%) | called by muse, mutect2, varscan2
- NDRG2 | c.862-15T>C | Intron (SNP) | VAF 15/178 reads (8%) | catalogued as rs8016835; called by muse, mutect2
- RBM43 | c.3+273_3+283del | Intron (DEL) | VAF 54/454 reads (12%) | called by mutect2, pindel
- SPEF2 | c.4448-3418G>A | Intron (SNP) | VAF 16/205 reads (8%) | catalogued as rs750804365; called by muse, mutect2
- STXBP6 | c.155-21655T>A | Intron (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- TEX9 | c.28-41T>G | Intron (SNP) | VAF 68/433 reads (16%) | called by muse, mutect2, varscan2
